Somatic mutation profile of tumor specimen TCGA-A6-2680-01A (aliquot TCGA-A6-2680-01A-01D-1408-10) from TCGA case TCGA-A6-2680, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage II; Age at diagnosis: 72.6 years (26,533 days).
Specimen TCGA-A6-2680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c422b1c-2416-471b-966d-4bb722c21cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2680-10A (Blood Derived Normal), aliquot TCGA-A6-2680-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93646891-3241-446f-802a-bd62112ecdde

The open-access MAF lists 126 somatic variants for this specimen: 87 protein-altering or splice-affecting, 29 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 29, Nonsense Mutation 7, 3'UTR 5, Frame Shift Del 4, Intron 3, Frame Shift Ins 3, Splice Region 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 120/242 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 36/54 reads (67%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64111630; called by muse, mutect2, varscan2
- ALDH1L2 | c.1782G>T p.W594C | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51558478; called by muse, mutect2, varscan2
- AMOTL1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1412081553, COSV54416150; called by muse, mutect2, varscan2
- AMZ1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as rs376751656; called by muse, mutect2, varscan2
- ARID1A | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 44/66 reads (67%) | catalogued as COSV61374989; called by muse, mutect2, varscan2
- ATP10A | c.4435C>T p.R1479* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1051708992, COSV63518302; called by muse, mutect2, varscan2
- ATP12A | c.1993A>T p.I665F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs531248710; called by muse, mutect2, varscan2
- BCLAF1 | c.533C>A p.P178Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV62143043, COSV62144533; called by muse, mutect2, varscan2
- BEND2 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs778717370, COSV66215972, COSV66217169; called by muse, mutect2, varscan2
- CACNA1G | c.3386G>A p.R1129Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1180552980, COSV61734091; called by muse, mutect2, varscan2
- CCDC73 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58794903, COSV58797375; called by mutect2, varscan2
- CDH18 | c.2302G>T p.G768* | Nonsense Mutation (SNP) | VAF 43/155 reads (28%) | catalogued as COSV56947231, COSV56953773; called by muse, mutect2, varscan2
- DTHD1 | c.1225G>T p.A409S (on ENST00000456874; = p.A244S on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62630056; called by muse, mutect2, varscan2
- EHD3 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs778226047; called by muse, mutect2, varscan2
- ENPP6 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs142786439; called by muse, mutect2, varscan2
- EP300 | c.5234C>G p.A1745G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV54337925; called by muse, mutect2, varscan2
- ERCC6L | c.3578C>T p.A1193V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs1226349013, COSV57820961; called by muse, mutect2
- ESRRG | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs1349900590, COSV100752977; called by muse, mutect2, varscan2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2, varscan2
- FAM3B | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs369029304; called by muse, mutect2
- FAM53A | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs751946591, COSV57402698; called by muse, mutect2, varscan2
- GOLGB1 | c.6062T>C p.V2021A | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1365182357; called by muse, mutect2, varscan2
- HBG2 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57963275; called by muse, mutect2
- IFI16 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as rs1232818629, COSV55538098; called by muse, mutect2, varscan2
- IGKV1-12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs764773736; called by muse, varscan2
- IGKV1D-13 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs1263282484; called by muse, mutect2
- KL | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs766210886; called by muse, mutect2, varscan2
- KNSTRN | c.823G>C p.A275P | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV51108576; called by muse, mutect2, varscan2
- KRT85 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs766037993, COSV57738797; called by muse, mutect2, varscan2
- LRRK2 | c.4372G>T p.D1458Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100109849; called by muse, mutect2, varscan2
- MAGEB1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs761222966, COSV66775935; called by muse, mutect2, varscan2
- NEB | c.19174C>T p.R6392C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs748561855, COSV50806444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUBPL | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749762773, COSV55277842; called by muse, mutect2, varscan2
- NUDT13 | c.794G>C p.W265S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61969647; called by muse, mutect2, varscan2
- OLFML2A | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368549348; called by muse, mutect2, varscan2
- PMEPA1 | c.70T>A p.C24S | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55694804, COSV99671959; called by muse, mutect2, varscan2
- POU6F2 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68875010; called by muse, mutect2, varscan2
- PRKDC | c.8186G>A p.R2729H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222301308, COSV100037775, COSV58051573, COSV58068122; called by muse, mutect2, varscan2
- PSMD5 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs377476205; called by muse, mutect2, varscan2
- PTGS2 | c.171G>A p.P57= | Splice Region (SNP) | VAF 65/163 reads (40%) | catalogued as COSV100821701, COSV66568839; called by muse, mutect2, varscan2
- RASGRF1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.49); catalogued as rs140190306; called by muse, mutect2, varscan2
- RPGR | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757712647, COSV58833935; called by muse, mutect2, varscan2
- SLC10A2 | c.270del p.F90Lfs*9 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as COSV55361593; called by mutect2, pindel, varscan2
- SLC2A8 | c.830T>A p.F277Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1210788148; called by muse, mutect2, varscan2
- SOX9 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV55428777; called by muse, mutect2, varscan2
- SPANXD | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65152939, COSV65153044; called by muse, varscan2
- SPTBN1 | c.4396A>G p.K1466E | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV100441410, COSV61691823; called by muse, mutect2, varscan2
- SYNE1 | c.21861C>T p.N7287= (on ENST00000367255 / NM_182961.4; = p.N7216= on NM_033071.3) | Splice Region (SNP) | VAF 19/99 reads (19%) | catalogued as rs372155442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAB2 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs374479022; called by muse, mutect2, varscan2
- TAS2R39 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs200819546, COSV101489393, COSV71470970; called by muse, mutect2, varscan2
- TENT5D | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs768296665, COSV57639667; called by mutect2, varscan2
- TRIM55 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as rs1279027783, COSV52548737; called by muse, mutect2, varscan2
- VSTM2B | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.442); catalogued as rs1170440590; called by muse, mutect2, varscan2
- WDFY4 | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs952804690, COSV57430791; called by muse, mutect2, varscan2
- ADAM10 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- AP4E1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- APC | c.4473del p.F1491Lfs*16 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by pindel, varscan2*
- BCAR3 | c.1670T>G p.L557R | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDK11B | c.1924T>G p.S642A | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL5A2 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CWF19L2 | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2J2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 58/103 reads (56%) | called by muse, mutect2, varscan2
- EFNB1 | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- FBXL14 | c.940T>C p.S314P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- FBXL15 | c.885dup p.V296Cfs*22 | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | called by mutect2, pindel, varscan2
- FEZF2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- GNB4 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GUCY1A2 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1B | c.7889G>T p.C2630F | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- MAP3K21 | c.1541G>T p.S514I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NELFA | c.1583G>A p.R528H (on ENST00000542778; = p.R517H on NM_005663.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP214 | c.3854_3867del p.P1285Rfs*3 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- PIEZO2 | c.6938G>T p.G2313V | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGR | c.1209dup p.W404Vfs*3 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- PPL | c.4587_4597del p.K1530Gfs*18 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- PRR19 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2
- PTPN5 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RAG1 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RGS3 | c.428T>A p.L143Q (on ENST00000350696 / NM_001282923.2; = p.L31Q on NM_017790.4) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX9 | c.1431dup p.T478Hfs*100 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- THAP7 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2
- UTP3 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF207 | c.801C>G p.S267R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, varscan2
- AMPD2 | c.1479G>A p.S493= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs777419165, COSV56647717, COSV56649546; called by muse, mutect2, varscan2
- ASTN2 | c.2490C>T p.S830= (on ENST00000313400 / NM_001365069.1; = p.S779= on NM_014010.5) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs376814866; called by muse, mutect2, varscan2
- CCT7 | c.1533C>T p.C511= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs377614021; called by muse, mutect2, varscan2
- CNTN1 | c.1719G>A p.A573= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs777069796, COSV61638906; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNHD1 | c.3492G>A p.A1164= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs1039587516; called by muse, mutect2, varscan2
- DSC2 | c.1620C>A p.I540= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as rs765374888, COSV51865373; called by muse, mutect2, varscan2
- DTNBP1 | c.531C>T p.H177= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs771033313, COSV59042952; called by muse, mutect2, varscan2
- EMILIN2 | c.2928C>T p.S976= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs753356543; called by muse, mutect2, varscan2
- FAT4 | c.13599G>T p.G4533= | Silent (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- HKDC1 | c.1329C>T p.L443= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1424596341, COSV100664385; called by muse, mutect2
- HRNR | c.6126C>T p.H2042= | Silent (SNP) | VAF 54/391 reads (14%) | catalogued as rs773303607, COSV100913784, COSV100914038; called by muse, mutect2, varscan2
- JAKMIP1 | c.1125G>A p.A375= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs150623866; called by muse, mutect2, varscan2
- KLF3 | c.222G>A p.S74= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs569064361; called by muse, mutect2, varscan2
- L1CAM | c.2715C>T p.P905= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs782031914; called by muse, mutect2, varscan2
- LTF | c.1776G>A p.L592= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs760360003; called by muse, mutect2, varscan2
- MROH2B | c.4300C>T p.L1434= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- NPAP1 | c.258G>A p.P86= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs746109641, COSV61508862, COSV61510753; called by muse, mutect2, varscan2
- PCDHB3 | c.810T>C p.D270= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PDZD2 | c.2691G>A p.T897= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs776430859; called by muse, varscan2
- RBMXL3 | c.1305C>T p.S435= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as rs782203878, COSV100407620; called by muse, mutect2, varscan2
- RYR1 | c.2709C>T p.H903= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1007637405, CD157288; called by muse, mutect2, varscan2
- SCML4 | c.453G>T p.L151= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1488372395; called by muse, mutect2, varscan2
- SLC35G3 | c.864C>T p.S288= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs202072050, COSV52012178; called by muse, mutect2, varscan2
- SOSTDC1 | c.597A>G p.K199= | Silent (SNP) | VAF 114/330 reads (35%) | catalogued as COSV61049656; called by muse, mutect2, varscan2
- SPEF2 | c.1926T>C p.G642= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV61544183; called by muse, mutect2, varscan2
- TNS1 | c.4875G>A p.T1625= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs201232462, COSV50725608; called by muse, mutect2, varscan2
- VWA5B2 | c.525C>T p.D175= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs749234716; called by muse, mutect2, varscan2
- WFIKKN2 | c.444G>A p.S148= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs903414878, COSV60959773; called by muse, mutect2, varscan2
- XKR8 | c.864C>T p.H288= | Silent (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- ATP1A3 | c.*52C>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs370433301; called by muse, mutect2, varscan2
- DCAF6 | c.1378+10992T>G | Intron (SNP) | VAF 94/244 reads (39%) | called by muse, mutect2, varscan2
- DOK3 | c.-25G>A | 5'UTR (SNP) | VAF 18/40 reads (45%) | catalogued as rs572684914; called by muse, mutect2, varscan2
- FOXC1 | c.*18A>C | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- GPER1 | c.*318G>A | 3'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs1162770840, COSV52470110; called by muse, mutect2, varscan2
- HPCAL1 | c.484+33A>G | Intron (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.176C>A | RNA (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.*25G>T | 3'UTR (SNP) | VAF 57/132 reads (43%) | called by muse, mutect2, varscan2
- OBSL1 | c.2953+495C>T | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as rs773248293; called by muse, mutect2, varscan2
- ZNF275 | c.*5G>A | 3'UTR (SNP) | VAF 35/58 reads (60%) | catalogued as rs3788754, COSV64704207; called by muse, mutect2, varscan2
